Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6805, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6805-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]	[REDACTED]	Formatted Path Report
------------	------------	-----------------------

[REDACTED]	[REDACTED]	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Excision of tumor Specimen size: Not specified Tumor site: Colon Tumor size: 5 x 5 x 0.8 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Subserosa Lymph nodes: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	[REDACTED]
------------	------------	---	------------

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file cbaf0fcb-4a5b-4c16-b851-dc110975af0c (TCGA-F4-6805.C6183FED-CFC7-4E3D-A934-845331FF5CCF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).